Somatic mutation profile of tumor specimen MP2PRT-PATHAI-TMP1-A (aliquot MP2PRT-PATHAI-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATHAI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (866 days).
Specimen MP2PRT-PATHAI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2f4ce35-8276-4420-967c-1531fd08d582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATHAI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATHAI-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00629fb9-87ea-4a5f-b1a2-953101e1af5e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 100/276 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- LOXHD1 | c.6269G>A p.R2090Q (on ENST00000642948; = p.R2028Q on NM_144612.7) | Missense Mutation (SNP) | VAF 142/565 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.115); catalogued as rs760286647, COSV56068768; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEX5L | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); catalogued as COSV55846728, COSV99829871; called by muse, mutect2
- RBMXL2 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1364827695, COSV60980263; called by muse, mutect2, varscan2
- TLR8 | c.2704C>T p.R902C (on ENST00000218032 / NM_138636.5; = p.R920C on NM_016610.4) | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.565); catalogued as COSV54317511; called by muse, mutect2, varscan2
- ZNF799 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV70122620; called by muse, mutect2, varscan2
- VASP | c.133_134insGCCAGGGGCCGCCA p.N45Sfs*71 | Frame Shift Ins (INS) | VAF 96/400 reads (24%) | called by pindel, varscan2
- AHNAK2 | c.2961C>T p.A987= | Silent (SNP) | VAF 172/720 reads (24%) | catalogued as rs371134105, COSV60917130; called by muse, varscan2
- AREL1 | c.780A>C p.S260= | Silent (SNP) | VAF 97/399 reads (24%) | called by muse, mutect2, varscan2
- CP | c.2790C>T p.Y930= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs958621868, COSV52833025; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDE4B | c.635-119_635-118insT | Intron (INS) | VAF 59/227 reads (26%) | called by mutect2, pindel, varscan2
